Surgical pathology report (de-identified scan), TCGA case TCGA-D3-A2JN, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site MD Anderson, specimen TCGA-D3-A2JN-06A (Metastatic).

100-0-3
Melanoma, NOS 8720/3
Site: lymph node, axillary C17.3
for 1/24/11

DIAGNOSIS

Patient ID — Sample ID

for 7/24/11

(A) RIGHT AXILLARY CONTENTS:

METASTATIC MALIGNANT TUMOR CONSISTENT WITH MELANOMA IN ONE OF SIXTEEN LYMPH NODES.

(B) ADDITIONAL MARGIN, LEVEL III:

Fibroadipose tissue, no tumor seen.

Entire report and diagnosis completed by

COMMENT

The tumor in the involved lymph node in specimen A measures at least 2.4 cm in maximum dimension. There is focal extranodal extension.

GROSS DESCRIPTION

(A) LEVELS I, II, III, RIGHT AXILLARY CONTENTS - Irregular fragment of fat (15.0 x 11.0 x 1.8 cm). Multiple nodes are dissected out. Nodes are ranging in size from 0.3 up to 2.5 cm. The largest node (2.5 x 2.5 x 2.0 cm) has a tan, rubbery cut surface with a rim of normal lymphoid tissue.

SECTION CODE: A1, four possible lymph nodes; A2, three possible lymph nodes; A3, two possible lymph nodes; A4, two possible lymph nodes; A5, two possible lymph nodes; A6, one lymph node, cross sectioned; A7, one lymph node, cross sectioned; A8-A12, representative sections of the largest node. Tissue from the enlarged node is given to tumor bank.

(B) ADDITIONAL MARGIN LEVEL III - Multiple fragments of fatty tissue (1.5 x 1.0 x 0.9 cm) in toto.

CLINICAL HISTORY

Melanoma.

SNOMED CODES

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

i. These tests have not been

Released by:

-----END OF REPORT-----

Source: NCI Genomic Data Commons file ed6feb01-dc57-43ed-b78a-f6441b656fb5 (TCGA-D3-A2JN.3509C797-78F7-46DC-B140-13C3FA25C00C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).